Somatic mutation profile of tumor specimen 68ef4aa9-00b0-4528-8828-4d3e43 (aliquot 68ef4aa9-00b0-4528-8828-4d3e43_D6_1) from CPTAC case 21BR010, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.9 years (25,914 days).
Specimen 68ef4aa9-00b0-4528-8828-4d3e43: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21c0c4e9-3d27-4b2c-88ed-1c25cb3d7e44.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 22bb2418-f3a9-4a2e-aceb-5f2c02 (Blood Derived Normal), aliquot 22bb2418-f3a9-4a2e-aceb-5f2c02_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b883be0a-c2c0-47d1-9780-8398c0fe94c1

The open-access MAF lists 39 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 9, Intron 3, 5'Flank 2, Frame Shift Ins 2, In Frame Ins 1, 3'UTR 1, Nonsense Mutation 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 66/236 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANGPTL7 | c.562T>A p.W188R | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63878035; called by muse, mutect2, varscan2
- ARHGEF15 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV62726127; called by muse, mutect2, varscan2
- CELSR2 | c.2177C>T p.P726L | Missense Mutation (SNP) | VAF 59/543 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs141335436; called by muse, mutect2, varscan2
- HHIP | c.1316G>A p.R439K | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV56844205; called by muse, mutect2, varscan2
- INAVA | c.1406C>T p.S469L | Missense Mutation (SNP) | VAF 363/871 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs868123316; called by muse, mutect2, varscan2
- LINGO4 | c.604C>G p.R202G | Missense Mutation (SNP) | VAF 39/445 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs775392267; called by muse, mutect2
- OR8K1 | c.318G>T p.Q106H | Missense Mutation (SNP) | VAF 55/313 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.743); catalogued as COSV54403917; called by muse, mutect2, varscan2
- ADAMTS5 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 18/526 reads (3%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- C15orf48 | c.282A>T p.Q94H | Missense Mutation (SNP) | VAF 72/411 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- C2orf81 | c.957_958insGGCGGCGCCCCCCGCCCCTCCGCG p.A319_S320insGGAPRPSA | In Frame Ins (INS) | VAF 22/77 reads (29%) | called by mutect2, varscan2*
- CXorf38 | c.307_314dup p.G106Afs*22 | Frame Shift Ins (INS) | VAF 34/140 reads (24%) | called by mutect2, varscan2
- ITGA2 | c.3313C>A p.P1105T | Missense Mutation (SNP) | VAF 24/540 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.155); called by muse, mutect2
- MAP2K4 | c.567C>A p.Y189* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- MAPKAPK2 | c.787T>A p.F263I | Missense Mutation (SNP) | VAF 136/322 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, varscan2
- NCOR1 | c.4391del p.H1464Lfs*8 | Frame Shift Del (DEL) | VAF 82/281 reads (29%) | called by mutect2, pindel, varscan2
- PAWR | c.912dup p.E305Rfs*4 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | called by mutect2, pindel, varscan2
- RASSF10 | c.1495T>G p.S499A | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); called by muse, mutect2
- SLC35B3 | c.584A>C p.Y195S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TYR | c.1089C>A p.H363Q | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- VPS13B | c.3630C>G p.D1210E | Missense Mutation (SNP) | VAF 77/401 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF318 | c.5951A>T p.D1984V | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ZNF629 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 61/412 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ACAN | c.7263C>T p.T2421= (on ENST00000560601 / NM_001369268.1; = p.T2345= on NM_001135.3) | Silent (SNP) | VAF 54/229 reads (24%) | called by muse, mutect2, varscan2
- ARF4 | c.312A>T p.A104= | Silent (SNP) | VAF 21/84 reads (25%) | called by muse, mutect2, varscan2
- CNGA1 | c.567A>G p.Q189= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as rs766164333; called by muse, mutect2
- GABRG2 | c.1095G>C p.S365= (on ENST00000361925 / NM_001375343.1; = p.S325= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 147/533 reads (28%) | called by muse, mutect2, varscan2
- KCNN2 | c.1566C>T p.H522= (on ENST00000264773; = p.H734= on NM_021614.4) | Silent (SNP) | VAF 72/324 reads (22%) | catalogued as rs370602863; called by muse, mutect2
- KNDC1 | c.5082C>A p.P1694= | Silent (SNP) | VAF 43/260 reads (17%) | called by muse, mutect2, varscan2
- PAMR1 | c.1842C>T p.N614= (on ENST00000619888 / NM_001001991.3; = p.N631= on NM_015430.4) | Silent (SNP) | VAF 47/210 reads (22%) | catalogued as rs201062106, COSV53511566; called by muse, mutect2, varscan2
- POP1 | c.1200C>T p.I400= | Silent (SNP) | VAF 57/179 reads (32%) | catalogued as rs577149443; called by muse, mutect2, varscan2
- SLC14A2 | c.2613C>T p.F871= | Silent (SNP) | VAF 66/422 reads (16%) | catalogued as rs747938849, COSV54913049; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504299 del TTG | 5'Flank (DEL) | VAF 6/29 reads (21%) | catalogued as rs559769337; called by pindel, varscan2
- ERCC6 | c.2382+873G>A | Intron (SNP) | VAF 10/51 reads (20%) | catalogued as rs1234912759; called by muse, mutect2, varscan2
- FAM131A | c.*591dup | 3'UTR (INS) | VAF 24/111 reads (22%) | called by mutect2, pindel, varscan2
- HSD3B7 | c.531+21C>T | Intron (SNP) | VAF 296/1132 reads (26%) | catalogued as rs371195720; called by muse, varscan2
- KIR3DX1 | chr19:54532767 del CC | 5'Flank (DEL) | VAF 22/274 reads (8%) | called by mutect2, pindel
- PNKP | c.199-10_199-9del | Intron (DEL) | VAF 46/260 reads (18%) | catalogued as rs749292876; called by pindel, varscan2
- WASF4P | n.218A>C | RNA (SNP) | VAF 19/672 reads (3%) | called by muse, mutect2
